Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9I7, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9I7-01A (Primary Tumor).

[page 1 of 4]
ICD-03

Pathology Report

Adenocarcinoma, duct NOS
8502/3
Site: Pancreas head
C25.0
JW 4/16/14

Final Diagnosis

- A. GALLBLADDER, CHOLECYSTECTOMY:
Gallbladder with chronic cholecystitis.
- B. LYMPH NODE, HEPATIC ARTERY, BIOPSY:
One lymph node with metastatic adenocarcinoma (1/1)
- C. BILIARY STENT, REMOVAL:
Biliary stent, gross diagnosis only.
- D. HEAD OF PANCREAS, PORTION OF DUODENUM AND DISTAL STOMACH, STANDARD PANCREATODUODENECTOMY:
Adenocarcinoma, moderately differentiated, pancreatic ductal origin
Perineural large-vessel and lymphatic invasion identified.
Carcinoma invades the duodenum, common bile duct, Ampulla and peripancreatic tissue.
Adjacent pancreatic parenchyma with panIN 3
Adenocarcinoma involves 1 of 27 lymph nodes (1/27)

I, _____, the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by _____

Comment

The carcinoma appears to be of pancreatic origin, based on the presence of extensive pancreatic intraepithelial neoplasia, and the lack of Ampullary precursors. The bulk of the invasive carcinoma is within the pancreas and secondarily involves the Ampulla and duodenum. Deeper sections examined of lymph node blocks D31-D32, D41 and D43.

Key Pathological Findings

Specimen type: _____

D: Pancreas-Exocrine Synoptic Data

SPECIMEN TYPE: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE: Invasive:

1.5 cm

*OTHER ORGANS RESECTED:

*OTHER ORGANS RESECTED: *Gallbladder

*Duodenum

*Distal Stomach

Ductal adenocarcinoma

[page 2 of 4]
HISTOLOGIC GRADE: G2: Moderately differentiated

Duodenum

Bile duct

PRIMARY TUMOR (pT): pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN): pN1a: Metastasis in single regional lymph node

Number examined: 28

Number involved: 2

DISTANT METASTASIS (pM): pMX: Cannot be assessed

MARGINS:

Margins free of tumor

*VENOUS (LARGE VESSEL) INVASION (V): *Present

*LYMPHATIC (SMALL VESSEL) INVASION (L): *Present

*PERINEURAL INVASION: *Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

*Pancreatic intraepithelial neoplasia (highest grade: PanIN 3)

*COMMENT(S): * Lymph node count includes the hepatic artery lymph node.

Specimen(s) Received

A GALLBLADDER
B HEPATIC ARTERY NODE
C BILIARY STENT (GROSS ONLY)
D WHIPPLE 4FS

Clinical History

AMPULLARY CANCER

Preoperative Diagnosis

Ampullary cancer.

Intraoperative Consultation

FSD1: PANCREATIC MARGIN:
Negative.

FSD2: COMMON BILE DUCT MARGIN:
Negative.

FSD3, FSD4: RETROPERITONEAL MARGIN (PERPENDICULAR):
Negative.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr.
in

[page 3 of 4]
I, M.D., have performed the intraoperative consultation (s) and issued the above diagnosis.

Gross Description

A. The specimen was received fresh in 4 containers. Specimen A is labeled "gallbladder". The specimen consists of a gallbladder which measures 8 x 4 x 3 cm. The serosa covering the gallbladder is pink-tan to dusky purple, smooth and glistening. No transforaminal perforations are grossly identified. The gallbladder's contents consist of a moderate amount of dark green, viscous bile. The mucosa of the gallbladder is elevated and grossly unremarkable. The cystic duct is patent to the flow of bile and has a 0.3 cm in diameter lumen. No lymph nodes are grossly identified attached to the gallbladder neck. The gallbladder's wall is mildly edematous, averaging 0.3 cm in thickness. No tissue was submitted to the Tissue Procurement Laboratory. Representative sections of the specimen are submitted in 2 cassettes, A1 and A2.

B. Specimen B is labeled "hepatic artery node". The specimen consists of a single, roughly ovoid, rubbery potential lymph node measuring up to 1.4 cm in greatest dimension. No tissue was submitted to the Tissue Procurement Laboratory. The lymph node is serially sectioned and is submitted entirely in 2 cassettes, B1 and B2.

C. Specimen C is labeled "biliary stent, gross only". The specimen consists of a blue plastic tube which measures 13.0 cm in length and 0.2 cm in diameter. The ends of the tube reveal a patent lumen which measures up to 0.2 cm in diameter. No sticky material is identified on the surface of the tube. The specimen is received for gross analysis only.

D. Specimen D is labeled "Whipple, frozen section on retroperitoneal margin, pancreatic margin, bile duct". The specimen consists of a pancreatic head (7 x 4 x 2.5 cm) with attached duodenum (16.0 cm in length and up to 4.5 cm in circumference at the level of distal resection margin) and distal portion of stomach (4.5 cm in length and up to 10.0 cm in circumference at the level of stapled gastric resection margin). The serosa of the stomach is pink-tan, smooth and glistening, while the outer surface of the duodenum is shaggy with a small amount of fibroadipose tissue attached. There is also a small amount of omental adipose tissue attached to the gastric wall. The peripheral aspects of the pancreatic head are composed of a small amount of adipose tissue which is ranging from 0.1 to 0.3 cm in thickness. Prior to sectioning, the specimen is inked as follows:

Anterior aspect of the pancreatic head:	Green.
Medial aspect (groove):	Red.
Stapled retroperitoneal margin:	Orange.
The remainder of the posterior aspect of the pancreatic head:	Black.
Parenchymal resection margin:	Black.
Common bile duct margin:	Blue.

On opening, the duodenum reveals an irregular, ill defined, sessile, focal hemorrhagic tumor (1.5 x 1 cm) which involves ampulla of Vater. On sectioning, the tumor measures up to 0.5 cm in depth and appears to involve adjacent portion of pancreatic head. The tumor also appears to involve the distal portion of common bile duct and main pancreatic duct. A 1.0 distal cm of the common bile duct, and the area of junction between main pancreatic duct and common bile duct are partially obstructed by the tumor. The portion of the common bile duct and the main pancreatic duct are located distal to the obstructed area, dilated up to 1.8 cm in circumference. The dilated portion of the common bile duct is 0.5 cm from the closest retroperitoneal resection margin. The remaining parenchyma of the pancreatic head is pale yellow, lobulated, rubbery to firm with some areas of intralobular fibrosis within parenchyma surrounding dilated portion of common bile duct. The portion of pancreatic parenchyma

[page 4 of 4]
adjacent to the parenchymal resection margin is grossly unremarkable. Several potential lymph nodes are grossly identified within fibroadipose tissue surrounding pancreatic head. The remaining mucosa of the duodenum and stomach are grossly unremarkable. Representative sections of the specimen are submitted to the Tissue Procurement Laboratory. Representative sections of the specimen are submitted for frozen section analysis and frozen section remnants are submitted in 4 cassettes as follows:

- FSD1: Pancreatic resection margin, tangential section.
- FSD2: Common bile duct margin, tangential section.
- FSD3, FSD4: Retroperitoneal margin (perpendicular cross sections) closest to the tumor.
- Additional sections of the specimen are submitted in 39 cassettes, D5-D43 as follows:
- D5-D6: Gastric resection margin, tangential section.
- D7: Duodenal resection margin, tangential section.
- D8: Ampulla of Vater with adjacent area of junction between main pancreatic duct and common bile duct.
- D9-D12: The remainder of the tumor involving ampulla of Vater with adjacent distal portion of common bile duct.
- D13-D15: Additional sections of the retroperitoneal margin in relation to the main pancreatic duct.
- D16-D19: Additional sections of the indurated parenchyma of the pancreatic head adjacent to the common bile duct and the main pancreatic duct.
- D20: Dilated portion of the common bile duct.
- D21: Additional section of the duodenum adjacent to the ampulla of Vater.
- D22-D24: Additional sections of the pancreatic head adjacent to the common bile duct and the main pancreatic duct.
- D25-D27: The remainder of the fibroadipose tissue, anterior aspect of the pancreatic head.
- D28: The remainder of the fibroadipose tissue attached to the medial aspect of the pancreatic head.
- D29-D30: The remainder of the fibroadipose tissue, superior aspect of the pancreatic head.
- D31-D34: The remainder of the adipose tissue of of the retroperitoneal aspect with potential lymph nodes.
- D35-D36: A portion of less omental adipose tissue in it's entirety.
- D37-D43: A portion of greater omentum with potential lymph nodes.

Source: NCI Genomic Data Commons file b0e7c5f1-0313-42fb-8619-b4713478fff7 (TCGA-3A-A9I7.6D8DBB3D-111F-4A77-9611-7F5A85A5F11A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).